Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAFM, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAFM-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Right orchiectomy; nonseminoma (EC 100%); diameter 3.8 cm; tumor confined to the testis; angioinvasion present; invasion in rete testis present.

Date of procurement (= date of orchiectomy):

pathologist

professor of pathology

ICD.O.3
Carcinoma, embryonal NOS
9070/3
Site R Testis NOS
C62.9
12/7/14

Source: NCI Genomic Data Commons file 89e76cb9-f554-4d27-a673-595395d54d86 (TCGA-2G-AAFM.3BE9BC69-9A9E-48AA-B636-24A30EC02D07.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).